Somatic mutation profile of tumor specimen 0DHOJ6 from CCDI case PBBTYR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.5 years (1,291 days).
Specimen 0DHOJ6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8203be0e-1f61-44d7-88ea-edb6b8b56255.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHOGW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/693a5a90-1e1b-4f4f-9f5b-ffb14422a9d1

The open-access MAF lists 9 somatic variants for this specimen: 1 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 6, Silent 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SSX2IP | c.1545G>A p.P515= | Silent (SNP) | VAF 80/1366 reads (6%) | catalogued as rs754121943; called by muse, mutect2
- ABCD4 | c.1457-100T>C | Intron (SNP) | VAF 19/127 reads (15%) | called by muse, varscan2
- ATP5F1A | c.140-80A>C | Intron (SNP) | VAF 36/295 reads (12%) | called by mutect2, varscan2
- GCNA | c.-73T>C | 5'UTR (SNP) | VAF 24/284 reads (8%) | catalogued as rs1178419723; called by muse, mutect2
- IKBKB | c.1689-92G>C | Intron (SNP) | VAF 16/148 reads (11%) | called by muse, varscan2
- KHDC4 | c.681+80T>G | Intron (SNP) | VAF 20/268 reads (7%) | catalogued as rs1334992364; called by muse, mutect2
- LRRC8B | c.*74A>G | 3'UTR (SNP) | VAF 46/338 reads (14%) | catalogued as rs891944719, COSV58375831; called by muse, varscan2
- NUP160 | c.1277+96T>C | Intron (SNP) | VAF 19/184 reads (10%) | called by muse, varscan2
- PPP1R13B | c.354+70T>C | Intron (SNP) | VAF 24/414 reads (6%) | called by muse, mutect2
